Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A19E, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A19E-06A (Metastatic).

ICD-0-3

Melanoma, NOS 8720/3

12/4/10

PATIENT HISTORY:

Per Dr. : note reviewed in MARS, the patient has a history of melanoma on the right arm 20 years ago.

PRE-OP DIAGNOSIS: Right axillary mass.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Right axillary dissection, removal axillary nodes right.

Site code: Axilla, NOS CL

FINAL DIAGNOSIS:

LYMPH NODES, RIGHT AXILLARY MASS, LYMPHADENECTOMY -

- A. POORLY DIFFERENTIATED METASTATIC NEOPLASM COMPATIBLE WITH MALIGNANT MELANOMA, INVOLVING FIVE (5) OUT OF FIFTEEN (15) LYMPH NODES (LARGEST LYMPH NODE 4 CM), WITH EXTENSIVE NECROSIS.
- B. EXTRACAPSULAR SPREAD IS OBSERVED.

COMMENT:

Although fifteen lymph nodes are counted, many of the larger masses described may represent multiple now confluent lymph nodes.

Immunohistochemical stains for S100 and NK1-C3 are positive. The neoplasm is negative for Cam 5.2, AE1/AE3, pankeratin, CD21, CD23, CD34, CK7, CK20, TTF and ER. Although it is also negative for Melan A, tyrosinase & HMB-45, these melanocytic markers can be lost in poorly differentiated melanocytic neoplasms.

Histopathologically, the differential would also include a metastatic peripheral nerve sheath tumor, but the remote history of melanoma favors a melanoma as diagnosis (in conjunction with the stains above).

Source: NCI Genomic Data Commons file 575fa3e8-76cb-441d-b7ff-815bc13e4e29 (TCGA-ER-A19E.C25995F9-1AD7-41E9-9DE9-372262733947.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).